Surgical pathology report (de-identified scan), TCGA case TCGA-G4-6298, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G4-6298-01A (Primary Tumor).

[page 1 of 2]
SPECIMENS:

A. RIGHT HEMICOLECTOMY

DIAGNOSIS:

- A. RIGHT HEMICOLECTOMY WITH PARTIAL SEGMENTS 5-6:
- MODERATELY TO POORLY DIFFERENTIATED ADENOCARCINOMA OF CECUM, TUMOR SIZE 6 X 3 CM.
- CARCINOMA INFILTRATING THROUGH BOWEL WALL AND INVADING TO ADJACENT LIVER PARENCHYMA.
- SURGICAL RESECTION MARGINS OF BOWEL AND LIVER TISSUE, FREE OF TUMOR.
- METASTATIC CARCINOMA PRESENT IN ONE OF THIRTY-SEVEN PERICOLIC LYMPH NODES (1/37).
- SEE TEMPLATE.

COLORECTAL CANCER TEMPLATE

Specimen Type:	Right hemicolectomy
Tumor Site:	Cecum
Tumor Configuration:	Exophytic, ulcerating
Tumor Size:	6 x 3 x 3 cm
Histologic Type:	Adenocarcinoma
Histologic Grade:	G2-3, moderately to poorly differentiated
Extent of Invasion:	Adjacent structure: liver
Margins:	Uninvolved by invasive carcinoma (proximal, distal, radial)
Venous/Lymphatic Invasion:	Indeterminate
Perineural Invasion:	Present
Additional Pathologic Findings:	NA
Extent of Resection:	R0: complete resection with grossly and microscopically negative margins
Lymph Nodes:	Positive (1/37)
Implants:	NA
EGFR Expression:	pending
Pathologic Stage:	pT4a, N1 Mx

SPECIMEN(S):

A. RIGHT HEMICOLECTOMY

CLINICAL HISTORY:

Colon cancer

GROSS DESCRIPTION:

RIGHT HEMICOLECTOMY WITH PARTIAL SEGMENTS 5-6

Received fresh is a segment of cecum with attached terminal ileum, overall measuring 15x14x6.5cm. Both ends are stapled. The attached terminal ileum is measuring 8cm in length, 3cm in diameter. Attached to the cecum also identified a small piece of liver segment measuring 3.0x6.0x2.0cm. The serosa is inked black. Opening of the cecum reveals close to the ileocecal valve, there is a tumor which measures 6.0x3.0x3.0cm on the mucosa and 4.5cm away from the stapled distal margin on the colon and less than 1cm away from the ileocecal valve. The surface of the tumor is ulcerated and sectioning through the tumor reveals the tumor is already penetrating through the muscularis propria reaching into the serosa, which might caused the adhesion to the liver. The rest of the mucosa in colon and terminal ileum are unremarkable. The sections are submitted as follows:

- A1: shaved margins from distal margin on the colon
- A2: shaved margins from terminal ileum
- A3-A4: representative sections across the tumor into the adhered liver
- A5: representative sections across the tumor into the ileocecal valve
- A6-A8: representative section from the deepest invaded tumor
- A9: representative sections from grossly unremarkable mucosa in terminal ileum and colon
- A10: representative sections from appendix including the base, mid portion and tip
- A11: additional section from the junction of tumor and liver.
- A12-A16: 24 presumptive lymph nodes

[page 2 of 2]
[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file eb9abc28-d650-46fb-b556-dc83474b67a9 (TCGA-G4-6298.BF7B5BF6-9223-412A-B98F-5E89761C5C8A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).